Somatic mutation profile of tumor specimen TCGA-IN-7808-01A (aliquot TCGA-IN-7808-01A-11D-2201-08) from TCGA case TCGA-IN-7808, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 59.1 years (21,569 days).
Specimen TCGA-IN-7808-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41d0fe84-4cc6-4bde-8635-786dc8b31d17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-7808-10A (Blood Derived Normal), aliquot TCGA-IN-7808-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97060b7a-2b07-4642-afec-aac52c62d001

The open-access MAF lists 118 somatic variants for this specimen: 92 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 24, Nonsense Mutation 10, Splice Site 4, Frame Shift Ins 2, Intron 2, In Frame Ins 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CWF19L1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 35/225 reads (16%) | catalogued as rs1554902760, COSV62499292; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1224T>G p.Y408* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as rs63750132, COSV51879445; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NLRP7 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as rs104895530, CM094504, COSV60174639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs199567128, COSV60665424; called by muse, mutect2, varscan2
- ALDH4A1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.849); catalogued as rs562344368, COSV51892576; called by muse, mutect2
- ALG1 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1398687891, COSV52157629; called by muse, mutect2, varscan2
- ARFGEF2 | c.4448C>T p.P1483L | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64212362; called by muse, mutect2
- ASB7 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs755374001, COSV58403802; called by muse, mutect2, varscan2
- BAP1 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 120/414 reads (29%) | catalogued as COSV56234502; called by muse, mutect2, varscan2
- CAD | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53027014; called by muse, mutect2, varscan2
- CD163L1 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as rs766336616, COSV58016401; called by muse, mutect2, varscan2
- CD276 | c.1121G>A p.R374Q (on ENST00000318443 / NM_001024736.2; = p.R156Q on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.364); catalogued as rs778780413, COSV59203698; called by muse, mutect2, varscan2
- CDH1 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.535); catalogued as COSV55732942, COSV99931292; called by muse, mutect2, varscan2
- CERS4 | c.155T>A p.M52K | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs754900307, COSV52166923; called by muse, mutect2, varscan2
- CHMP4B | c.368+2T>C p.X123_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV54136047; called by muse, mutect2
- CHRNB2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771286419, COSV63807831; called by muse, mutect2, varscan2
- CSF2RB | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1290001450, COSV53257892, COSV99453231; called by muse, mutect2, varscan2
- DMRTC2 | c.845C>A p.T282K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV99523413; called by muse, mutect2, varscan2
- EFTUD2 | c.2304A>C p.Q768H | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53655625, COSV53656540; called by muse, mutect2
- EPSTI1 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV58045486; called by muse, mutect2
- ESCO1 | c.2406C>G p.S802R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV52519856, COSV52523143; called by muse, mutect2, varscan2
- FAM90A1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1362889210, COSV56712081; called by muse, mutect2, varscan2
- FGF20 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51660954, COSV51661400; called by muse, mutect2, varscan2
- FRMD6 | c.1118C>T p.A373V (on ENST00000344768 / NM_001267046.2; = p.A365V on NM_152330.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs371612348; called by muse, mutect2, varscan2
- FXR1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as rs374389670; called by muse, mutect2
- GHRHR | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.549); catalogued as rs757742182, COSV58196488; called by muse, mutect2, varscan2
- GOLGA3 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV52631535; called by muse, mutect2, varscan2
- H3C13 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV58944256; called by muse, mutect2, varscan2
- HECTD2 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV53221065, COSV53222171; called by muse, mutect2, varscan2
- HIVEP3 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs766672681, COSV56015641; called by muse, mutect2, varscan2
- IGSF8 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as rs771772836, COSV58758077; called by muse, mutect2, varscan2
- IGSF9B | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs201162330, COSV58067726; called by muse, varscan2
- IL18R1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as rs1443035361, COSV52124643; called by muse, mutect2, varscan2
- KANSL1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768152581, COSV52265936; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KCTD8 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs964170538, COSV63585887; called by muse, mutect2
- KIAA1109 | c.7880G>A p.G2627E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV52673539; called by muse, mutect2, varscan2
- KRT4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs758810156, COSV53407310; called by muse, mutect2, varscan2
- KRT6C | c.912+2T>A p.X304_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | catalogued as COSV52877712, COSV52877842; called by muse, mutect2, varscan2
- LAMA1 | c.1580G>C p.G527A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV67537175; called by muse, mutect2, varscan2
- LMBRD2 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56950218; called by muse, mutect2, varscan2
- LRIG1 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 27/197 reads (14%) | catalogued as rs1470426415, COSV56240180; called by muse, mutect2, varscan2
- MACF1 | c.20446G>T p.V6816L (on ENST00000372915; = p.V4861L on NM_012090.5) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | catalogued as COSV57121503, COSV57144986; called by muse, mutect2, varscan2
- MANEA | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV62589682; called by muse, mutect2, varscan2
- MICALL1 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1006475452, COSV53240783; called by muse, mutect2, varscan2
- MNS1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1428933655, COSV53068250; called by muse, mutect2, varscan2
- NCOR1 | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV51975011; called by muse, mutect2, varscan2
- NEUROG2 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100511965, COSV57637344; called by muse, mutect2
- NRXN1 | c.3766G>A p.G1256R | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs928022072, COSV100640814, COSV60499596, COSV60512257, COSV60523646; called by muse, mutect2
- OR1C1 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68715737; called by muse, mutect2
- OR4F6 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV61026656, COSV61026820; called by muse, mutect2
- OR51G2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as rs750568250, COSV58992987; called by mutect2, varscan2
- OR52A5 | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV56615298; called by muse, mutect2, varscan2
- OR8I2 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs749949853, COSV56168001, COSV56168420; called by muse, mutect2, varscan2
- OSBPL6 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 29/176 reads (16%) | catalogued as COSV51918205; called by muse, mutect2, varscan2
- PABPC3 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs768632260, COSV55798152; called by muse, varscan2
- PCLO | c.10060G>T p.D3354Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61635696; called by muse, mutect2, varscan2
- PIK3C2B | c.3992T>C p.L1331P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100916134, COSV65811512; called by muse, mutect2, varscan2
- PKD1 | c.3907G>A p.A1303T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs761686050, COSV51916510; called by muse, mutect2, varscan2
- POP1 | c.90A>T p.R30S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV62892794; called by muse, mutect2
- PTPDC1 | c.2037+1G>A p.X679_splice (on ENST00000375360 / NM_177995.3; = p.X731_splice on NM_152422.4) | Splice Site (SNP) | VAF 19/43 reads (44%) | catalogued as rs1278084358, COSV56623274; called by muse, mutect2, varscan2
- RASGRF1 | c.2496G>C p.Q832H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV67250037; called by muse, mutect2, varscan2
- RBM38 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765064896, COSV100654853; called by muse, mutect2, varscan2
- RNASE9 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs149710160, COSV58880441; called by muse, mutect2, varscan2
- SELENBP1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs781731476, COSV64373503; called by muse, mutect2
- SERPINA5 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs866630753, COSV61573556, COSV61574034; called by muse, mutect2, varscan2
- SLC26A4 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200229408, CM134466, CM138425, COSV55916721; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- SLC49A3 | c.225C>G p.Y75* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV59140331, COSV59140413; called by muse, mutect2, varscan2
- ST8SIA4 | c.868A>T p.R290* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV51508323, COSV51509997; called by muse, mutect2, varscan2
- STAG1 | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs762160605, COSV52610194, COSV99365135; called by muse, mutect2, varscan2
- TECTA | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1390890390, COSV50691392, COSV50708999; called by muse, mutect2, varscan2
- TGM6 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1275709205, COSV52480072; called by muse, mutect2, varscan2
- TMEM202 | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58982569; called by muse, mutect2, varscan2
- TNFSF13B | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as COSV65516233; called by muse, mutect2, varscan2
- TRDMT1 | c.713T>G p.I238S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV58319344; called by muse, mutect2, varscan2
- TRIM51 | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99792738; called by muse, mutect2, varscan2
- TRPM6 | c.5538A>T p.Q1846H | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV62510473; called by muse, mutect2
- TUBB4A | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as rs587777429, CM146108, COSV51155246; called by muse, mutect2, varscan2
- USF3 | c.3805G>A p.V1269M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs766437240, COSV57072827; called by muse, mutect2, varscan2
- WDR18 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV52121897; called by muse, mutect2, varscan2
- WDR88 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV63451454; called by muse, mutect2
- ZFYVE1 | c.1987+1G>C p.X663_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV59611220; called by muse, varscan2
- ZNF208 | c.3244G>T p.E1082* | Nonsense Mutation (SNP) | VAF 57/184 reads (31%) | catalogued as COSV68105762; called by muse, mutect2, varscan2
- ZNF382 | c.1397G>T p.C466F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53088419; called by muse, mutect2, varscan2
- ZNF512B | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs373018067; called by muse, mutect2, varscan2
- ZNF827 | c.3197A>G p.K1066R | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV65227260; called by muse, mutect2, varscan2
- ZNF85 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as COSV60214798; called by muse, mutect2, varscan2
- BIRC6 | c.14366_14367insATC p.T4789_M4790insS | In Frame Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- CMPK1 | c.176_177dup p.G60Mfs*41 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- FANCM | c.3950dup p.N1317Kfs*2 | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- ZKSCAN5 | c.947_979del p.G316_R326del | In Frame Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- AC100868.1 | c.1651A>C p.R551= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV51843046; called by muse, mutect2
- AMER2 | c.444C>T p.G148= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs772114458, COSV63437330; called by muse, mutect2, varscan2
- CEP70 | c.732C>T p.N244= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs766910524, COSV53875746; called by muse, mutect2, varscan2
- CHD9 | c.5220C>T p.A1740= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV54610548; called by muse, mutect2, varscan2
- DCAF4L1 | c.1083C>T p.D361= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs185284835; called by muse, mutect2, varscan2
- DDHD1 | c.522A>G p.T174= (on ENST00000323669; = p.T371= on NM_030637.3) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1264795205, COSV60359363; called by muse, mutect2, varscan2
- DLGAP4 | c.2058C>T p.T686= (on ENST00000339266 / NM_001365621.1; = p.T147= on NM_183006.4) | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100211389; called by muse, mutect2, varscan2
- DSG4 | c.1452T>C p.C484= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV57391844; called by muse, mutect2, varscan2
- EDNRA | c.1203C>T p.N401= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs760631772, COSV60097603; called by muse, mutect2, varscan2
- EPX | c.267C>T p.A89= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs138191637, COSV56598694; called by muse, mutect2, varscan2
- GFRAL | c.1125T>A p.T375= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100474895; called by muse, mutect2
- HBG2 | c.252C>G p.G84= | Silent (SNP) | VAF 13/200 reads (7%) | catalogued as COSV57963608; called by muse, mutect2
- LTBP4 | c.2799C>G p.G933= (on ENST00000308370 / NM_001042544.1; = p.G896= on NM_003573.2) | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV52581740; called by muse, mutect2, varscan2
- MYH4 | c.114C>A p.V38= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as COSV55118320; called by muse, mutect2, varscan2
- NOC4L | c.1032C>T p.R344= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as rs772358688, COSV57957271; called by muse, mutect2, varscan2
- NUP205 | c.3984G>A p.A1328= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as rs181055416, COSV53658850; called by muse, mutect2, varscan2
- OR4A47 | c.612T>C p.A204= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV71444967; called by muse, mutect2, varscan2
- PCDHGB4 | c.1986C>T p.F662= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs1395147259, COSV53949820; called by muse, mutect2, varscan2
- PCDHGB6 | c.675C>T p.T225= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1476847671, COSV53949834, COSV99542384; called by muse, mutect2, varscan2
- RIMS2 | c.1299T>C p.P433= (on ENST00000666250 / NM_001348490.2; = p.P241= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV51682181; called by muse, mutect2, varscan2
- TTN | c.18G>A p.P6= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs755302800, COSV59895874; called by mutect2, varscan2
- ZNF132 | c.2046T>C p.T682= | Silent (SNP) | VAF 38/185 reads (21%) | catalogued as COSV54234997; called by muse, mutect2, varscan2
- ZNF346 | c.303G>A p.V101= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV56156555; called by muse, mutect2, varscan2
- ZNF471 | c.1542T>G p.P514= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV57291315; called by muse, mutect2, varscan2
- AQR | c.471+1094G>A | Intron (SNP) | VAF 26/265 reads (10%) | catalogued as rs767183531, COSV50030501, COSV50038860; called by muse, mutect2
- EPHA6 | c.2784+10226T>G | Intron (SNP) | VAF 6/53 reads (11%) | catalogued as COSV101063769; called by muse, mutect2, varscan2
